Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9KY, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9KY-01A (Primary Tumor).

[page 1 of 4]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

ICD-6-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
J451123114

Gross description:

1. (Prostate gland): Prostate gland: Weight: 23 g, Volume: 18 ml, Size: 4 x 4 x 3 cm. Adherent seminal vesicles and deferent duct: right side: 2 cm, left side: 2.5 cm. The surface is marked with green ink on the right side, blue ink on the left side. On the right recto-lateral surface a 3.5 x 2.5 cm measuring tissue defect marked with yellow ink. On the left recto-lateral surface a 3.5 x 2 cm measuring tissue defect marked with yellow ink. Apical periurethral a funnel shaped 0.8 x 0.8 cm tissue defect marked with red ink. Total of the cross sections: 1.5 cm. Attached to the prostate a 4 x 4 x 2 cm measuring urinary bladder wall (according to clinical data: bladder outlet).
2. (Lymph nodes, right side): 7 x 4.5 x 2.5 cm measuring adipose tissue containing 7 nodes measuring up to 6 x 2 x 0.6 cm.
3. (Lymph nodes, left side): 5 x 3.5 x 2 cm measuring adipose tissue containing 5 nodes measuring up to 7 x 1.5 x 0.7 cm.

Microscopy:

1. Apex right and left: Right 5 tissue blocks, left 6 tissue blocks (total 11 tissue blocks). 2 cross sections: Right 8 tissue blocks, left 8 tissue blocks (total 16 tissue blocks). Basis right and left: Right 8 tissue blocks, left 8 tissue blocks (total 16 tissue blocks). Seminal vesicles right and left: Right 3 tissue blocks, left 3 tissue blocks (total 6 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Frozen lymph nodes right: 12 tissue blocks.
3. Frozen lymph nodes left: 9 tissue blocks.

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 70%, Gleason 4: 30%). Tumor involves both lobes. Maximum tumor diameter: 38 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 12 tissue blocks, thereof 6 adjacent blocks with the main focus near the attached urinary bladder wall (contact length: 22 mm, invasion depth 3.0 mm). Tumor infiltration of both seminal vesicles. Positive surgical margin in 29 blocks, thereof 9 adjacent blocks with the main focus in the attached urinary bladder wall (contact area: 40 mm x 25 mm, Gleason 4 and 5). Tumor-free periurethral resection margin. Enclosed parts of the urinary bladder with prostatic adenocarcinoma, urothelium without dysplasia.

[page 2 of 4]
Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor-free deferent ducts on both sides.

2. (Lymph nodes, right side): Nine tumor-free lymph nodes (0/9).

3. (Lymph nodes, left side): One lymph node metastasis (7 mm without extracapsular invasion) in a total of six lymph nodes (1/6).

Tumor classification

(in consideration of the intraoperative frozen-section, parallel report and immunohistochemical analyses):

pT4, Gleason 5+4=9 (Gleason 5: 70%, Gleason 4: 30%), maximum tumor diameter: 38 mm, tumor volume approx. 20.6 ml (Gleason 5: 14.4 ml, Gleason 4: 6.2 ml), pN1 (2/16), L1, V0, R1

Comments:

Tumor infiltration of both seminal vesicles in tissue blocks BR1B, BR2B, BR3A, SBR1, SBR2, BL1B, BL2A, BL2B, BL3A, BL3B.

Tumor infiltration into peri-prostatic adipose tissue in tissue blocks AR1B, BR1B, SBR2, SBL1, SBL2, SBL3, A2, A3, A4, A5, A6, and A7.

In the preceding intraoperative frozen section prostatic adenocarcinoma with positive surgical margin was found on both sides.

The consequently bilateral neurovascular resection revealed tumor infiltration on both sides. In addition, there was a questionable tumor infiltration in the sample „apex, right side“ and tumor infiltration in the sample “sphincter, right side”. The parallel samples “secondary resection material, bladder neck” and “secondary resection margin, left pedicle” revealed tumor infiltration.

It can be assumed, that the positive lateral surgical margin on both sides (tissue block AR1A, R1A, LA1A, L2A, L2B) are covered by the bilateral neurovascular resection. The contact sites in the prostatic base (BR1A, BR1B, BR2A, BR2B, BR3A, BL1A, BL1B, BL2A, BL2B, BL3A, and BL4A) may be covered by the attached urinary bladder wall.

However, due to positive surgical margin in tissue blocks SBR1, SBR2, SBL2, A1, A2, A3, A4, A5, A6, A7, A8 and A9 as well a tumor infiltration of the frozen section “sphincter right” and the sample “secondary resection material, bladder neck” and “secondary resection material, left pedicle” of the parallel sample it has to be assumed that the tumor was **not** entirely resected.

In addition, there was an additional lymph node metastasis (1/1) in the pre-prostatic adipose tissue in a parallel sample.

Immunohistochemical analyses (D2-40, CD31) revealed lymphatic invasion. Venous vasion was not detected.

[page 3 of 4]
One macroscopic image for tumor mapping.

See dx discrepancy form
for Gleason 5+5.

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason 5+4	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Gleason 5+5	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Frozen sample tissue block submitted to TCGA has a different Gleason score than the frozen tissue block that was used for diagnosis.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature Date

Source: NCI Genomic Data Commons file 3ece7d0a-0143-490d-a8aa-ce147f3d3428 (TCGA-ZG-A9KY.2E48E905-FCAF-4A5F-A2E0-600276051562.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).